Gene-level copy-number profile of tumor specimen TCGA-14-0736-02A from TCGA case TCGA-14-0736, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.9 years (18,219 days).
Specimen TCGA-14-0736-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c4461728-d337-44be-8c24-e71283ec573a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-0736-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e86f17e5-e04a-4789-bc57-10eaea5e21a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,413; copy number 1: 16,458; copy number 2: 39,583; copy number 3: 977; copy number 4: 152; copy number 5: 81; copy number 6: 37; copy number 9: 1; copy number 10: 13; copy number 11: 330; copy number 12: 113; copy number 13: 96; copy number 14: 8; copy number 17: 9; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-0736-02A-01D-2002-01): tumor purity 0.46, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,668,995–46,834,095, 11 genes (within-gene range 0–2): ALS2CL, TMIE, AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P, PRSS42P.
- chr6:13,264,861–13,487,662, 5 genes: AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1.
- chr6:70,856,679–70,957,060, 1 gene (within-gene range 0–1): B3GAT2.
- chr12:30,320,834–30,321,617, 1 gene: AC078776.1.
- chr14:33,597,057–33,600,989, 1 gene: AL161851.1.
- chr22:25,279,529–25,520,854, 13 genes: AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 690 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene, copy number 9: RPL31P12.
- chr1:154,567,778–154,580,013, 2 genes, copy number 5: CHRNB2, AL592078.1.
- chr7:10,449,820–10,779,944, 1 gene, copy number 10 (within-gene range 4–13): MGC4859.
- chr7:10,702,676–14,010,763, 32 genes, copy number 6–13: AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA.
- chr7:15,066,207–16,502,504, 12 genes, copy number 5 (within-gene range 4–5): AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1.
- chr7:16,791,811–16,833,433, 1 gene, copy number 10 (within-gene range 4–10): AGR2.
- chr7:16,859,412–17,467,256, 11 genes, copy number 5–12 (within-gene range 3–12): AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2.
- chr7:17,940,503–22,732,002, 55 genes, copy number 5: AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6.
- chr7:23,105,758–23,177,914, 1 gene, copy number 10 (within-gene range 4–10): KLHL7.
- chr7:23,181,841–23,311,729, 5 genes, copy number 10: NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1.
- chr7:26,152,198–29,195,451, 86 genes, copy number 12–20 (within-gene range 4–33) (broad region; genes not listed).
- chr7:30,852,273–37,449,249, 105 genes, copy number 5–14 (within-gene range 4–14) (broad region; genes not listed).
- chr7:50,093,279–50,094,123, 1 gene, copy number 10: AC034148.1.
- chr7:51,614,251–67,362,950, 377 genes, copy number 6–17 (within-gene range 2–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,454. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
